Somatic mutation profile of tumor specimen TCGA-BP-4961-01A (aliquot TCGA-BP-4961-01A-01D-1462-08) from TCGA case TCGA-BP-4961, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 47.3 years (17,284 days).
Specimen TCGA-BP-4961-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f428e547-35f8-4120-b6c9-4feadb313abd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4961-11A (Solid Tissue Normal), aliquot TCGA-BP-4961-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/502e5e53-614c-4d99-80cc-37209c5d39e5

The open-access MAF lists 40 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 21, Silent 11, Frame Shift Ins 3, Frame Shift Del 3, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANPEP | c.2074T>C p.Y692H | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55594389; called by muse, mutect2, varscan2
- DENND6B | c.1201A>C p.K401Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV69807555; called by muse, mutect2, varscan2
- DNTTIP2 | c.100C>A p.H34N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV63284538; called by muse, mutect2, varscan2
- ERICH3 | c.3674G>A p.G1225E | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV58610360; called by muse, mutect2, varscan2
- FSTL4 | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.872); catalogued as COSV54784037; called by muse, mutect2, varscan2
- GPAA1 | c.351G>C p.E117D | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.823); catalogued as COSV60156458; called by muse, mutect2, varscan2
- HSPA12A | c.220T>C p.F74L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV65023763; called by muse, mutect2, varscan2
- KCND3 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as COSV56188536; called by muse, mutect2, varscan2
- KIF20B | c.944T>C p.L315P | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53314617; called by muse, varscan2
- KMT2C | c.12143C>A p.S4048* | Nonsense Mutation (SNP) | VAF 19/124 reads (15%) | catalogued as COSV51494885; called by muse, mutect2, varscan2
- MARK2 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs774000976, COSV59280888; called by muse, mutect2, varscan2
- MC5R | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs757556972, COSV61255578; called by muse, mutect2, varscan2
- MYO9A | c.1296C>G p.I432M | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61856738; called by muse, mutect2, varscan2
- PATJ | c.3024G>C p.R1008S | Missense Mutation (SNP) | VAF 9/264 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1020691187, COSV57170730; called by muse, mutect2
- PCDHGA1 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV65299083; called by muse, mutect2
- RRP12 | c.3568-1G>T p.X1190_splice | Splice Site (SNP) | VAF 34/133 reads (26%) | catalogued as COSV59671100; called by muse, mutect2, varscan2
- SAP130 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as COSV52102257; called by muse, mutect2
- SERPINB5 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV66976064; called by muse, mutect2, varscan2
- SLC12A2 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52471369, COSV52475889; called by muse, mutect2, varscan2
- SUPT5H | c.2653T>C p.Y885H | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV63241820; called by muse, mutect2, varscan2
- VWA3A | c.3217G>A p.V1073I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.214); catalogued as COSV55394547; called by muse, mutect2, varscan2
- ZBTB41 | c.181A>G p.R61G | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); catalogued as COSV66359980; called by muse, mutect2, varscan2
- ZNF770 | c.832T>A p.S278T | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs750625661, COSV62544885; called by muse, mutect2, varscan2
- DTNA | c.609dup p.V204Sfs*39 | Frame Shift Ins (INS) | VAF 39/177 reads (22%) | called by mutect2, pindel, varscan2
- FLCN | c.1250del p.F417Sfs*51 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- MAGI2 | c.849dup p.K284Efs*6 | Frame Shift Ins (INS) | VAF 30/133 reads (23%) | called by mutect2, pindel, varscan2
- PTPN4 | c.1132dup p.I378Nfs*3 | Frame Shift Ins (INS) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- RASA1 | c.2914_2918del p.D972Tfs*6 | Frame Shift Del (DEL) | VAF 20/167 reads (12%) | called by mutect2, pindel, varscan2
- SPPL2C | c.805del p.L269Cfs*66 | Frame Shift Del (DEL) | VAF 25/163 reads (15%) | called by mutect2, pindel, varscan2
- ACAN | c.2181T>A p.T727= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV61368278; called by muse, mutect2, varscan2
- ASTN2 | c.1371T>C p.C457= (on ENST00000313400 / NM_001365069.1; = p.C406= on NM_014010.5) | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV57813329; called by muse, mutect2, varscan2
- CHD3 | c.3420C>T p.G1140= | Silent (SNP) | VAF 10/123 reads (8%) | catalogued as rs774851044, COSV57879756; called by muse, mutect2
- COPG2 | c.627T>C p.L209= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV58406761; called by muse, mutect2, varscan2
- CXXC1 | c.1962C>T p.A654= | Silent (SNP) | VAF 49/153 reads (32%) | catalogued as COSV53276636; called by muse, mutect2, varscan2
- HMGCS2 | c.237G>T p.V79= | Silent (SNP) | VAF 42/182 reads (23%) | catalogued as COSV65569099; called by muse, mutect2, varscan2
- MAP4 | c.1329G>A p.E443= | Silent (SNP) | VAF 46/141 reads (33%) | catalogued as COSV64244247; called by muse, mutect2, varscan2
- MYOM1 | c.1869A>G p.G623= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV55303237; called by muse, mutect2
- OSBPL5 | c.90G>A p.R30= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV55145289; called by muse, mutect2
- PCF11 | c.1779T>C p.S593= | Silent (SNP) | VAF 37/166 reads (22%) | catalogued as COSV53537077; called by muse, mutect2, varscan2
- ZNF283 | c.1485C>T p.T495= | Silent (SNP) | VAF 9/196 reads (5%) | catalogued as COSV61032541, COSV61033096; called by muse, mutect2
